Somatic mutation profile of tumor specimen TCGA-S9-A7QY-01A (aliquot TCGA-S9-A7QY-01A-11D-A34A-08) from TCGA case TCGA-S9-A7QY, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 35.2 years (12,853 days).
Specimen TCGA-S9-A7QY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a36b2f7-259f-4d1b-b65c-304d2ea38893.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7QY-10A (Blood Derived Normal), aliquot TCGA-S9-A7QY-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d68cfc6a-eebc-42cf-a247-c7c4847e57d8

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 25, Silent 10, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 21/72 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.2345A>G p.E782G | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99176315; called by muse, mutect2
- ATP10D | c.2363C>T p.S788F | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99905126; called by muse, mutect2
- BNIP1 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs571663655, COSV99199362; called by muse, mutect2, varscan2
- CCDC121 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV53118041, COSV99269811; called by muse, mutect2, varscan2
- CCNB1 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as rs776088624, COSV99841166; called by muse, mutect2, varscan2
- CMC2 | c.140G>T p.C47F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99548114; called by muse, mutect2, varscan2
- DCAF8L1 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs146103278, COSV71595418; called by muse, mutect2
- DNAH8 | c.3053G>A p.R1018H | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.749); catalogued as rs777609925, COSV59464146, COSV59471463; called by muse, mutect2, varscan2
- ECEL1 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1454248258, COSV100458427; called by muse, mutect2
- ENTPD6 | c.313A>T p.M105L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100736973; called by muse, mutect2
- GLI3 | c.2050T>C p.S684P | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.703); catalogued as COSV101229724; called by muse, mutect2
- HK3 | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99457797; called by muse, mutect2, varscan2
- INTS6L | c.1601C>T p.T534M | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.109); catalogued as rs781801546, COSV100878013, COSV100878155; called by muse, mutect2
- LPAR3 | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs528048334, COSV101004674; called by muse, mutect2, varscan2
- MTPN | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 22/293 reads (8%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.956); catalogued as COSV101262927, COSV67599324; called by muse, mutect2
- QRICH1 | c.1671G>A p.K557= | Splice Region (SNP) | VAF 10/130 reads (8%) | catalogued as COSV100676647; called by muse, mutect2
- RAP2C | c.466C>A p.L156I | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as rs371502735, COSV100747270; called by muse, mutect2
- REPS1 | c.910A>C p.I304L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV99238408; called by muse, mutect2, varscan2
- RGS22 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100692982; called by muse, mutect2, varscan2
- SENP7 | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV58620934; called by muse, mutect2, varscan2
- SLC2A14 | c.181-1G>A p.X61_splice | Splice Site (SNP) | VAF 24/71 reads (34%) | catalogued as COSV100533521; called by muse, mutect2, varscan2
- TAZ | c.285-1G>T p.X95_splice | Splice Site (SNP) | VAF 35/108 reads (32%) | catalogued as COSV99185810; called by muse, mutect2, varscan2
- TEX2 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV99366788; called by muse, mutect2, varscan2
- UGGT1 | c.4348A>G p.N1450D | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1429685216, COSV99390228; called by muse, mutect2, varscan2
- UQCRC2 | c.711T>G p.F237L | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV99193270; called by muse, mutect2, varscan2
- ZNF318 | c.6346G>A p.G2116S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.225); catalogued as COSV100545941; called by muse, mutect2
- ZNF460 | c.1216G>T p.D406Y | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.888); catalogued as COSV100828027; called by muse, mutect2, varscan2
- ADCY2 | c.522C>T p.S174= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as rs758825950, COSV57886365; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1962G>A p.L654= (on ENST00000361735 / NM_015935.5; = p.L568= on NM_014955.3) | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as COSV100675766; called by muse, mutect2, varscan2
- NYX | c.930C>T p.N310= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV100699361; called by muse, mutect2, varscan2
- OPN1MW | c.861C>T p.F287= | Silent (SNP) | VAF 22/203 reads (11%) | catalogued as rs781952173; called by muse, mutect2, varscan2
- OR4S1 | c.810C>T p.I270= | Silent (SNP) | VAF 39/125 reads (31%) | catalogued as COSV100180168; called by muse, mutect2, varscan2
- PHEX | c.387C>T p.T129= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs777298207, COSV101039388; called by muse, mutect2, varscan2
- PUDP | c.324C>T p.P108= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV101127790; called by muse, mutect2
- RFX4 | c.654A>G p.R218= (on ENST00000392842 / NM_213594.3; = p.R124= on NM_032491.6) | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as COSV99985345; called by muse, mutect2, varscan2
- TUT4 | c.2379C>T p.H793= | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as rs140552770; called by muse, mutect2, varscan2
- UBXN6 | c.1095C>T p.F365= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs767847248, COSV100010813; called by muse, mutect2, varscan2
